CPTAC case C3N-03052 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/570d34b4-1b20-4124-9086-5e4f678ad64d

Demographics
Sex at birth: male; Race: asian; Year of birth: 1955; Vital status: Dead; Days to death: 791 days (2.2 years); Year of death: 2020; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 63.0 years (23,009 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 791 days (2.2 years); Progression or recurrence: no; Days to last follow up: 703 days (1.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 16; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 377 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 703 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 703 days (1.9 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 703 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 80 kg; Height: 175 cm; BMI: 26.12; DLCO (% of predicted): 99; FEV1 before bronchodilator (% of reference): 82.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40; Cigarettes per day: 20; Tobacco smoking onset year: 1977; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 45.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03052-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 192 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03052-21: Section location: Right Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3N-03052-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 205 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03052-22: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03052-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 293 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 15 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03052-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
